Somatic mutation profile of tumor specimen TCGA-GL-A4EM-01A (aliquot TCGA-GL-A4EM-01A-11D-A25F-10) from TCGA case TCGA-GL-A4EM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.0 years (22,635 days).
Specimen TCGA-GL-A4EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90c570d7-d5e5-4bb0-b6fe-15d50ab74523.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-A4EM-10A (Blood Derived Normal), aliquot TCGA-GL-A4EM-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98007d3a-a3f6-4d92-b0b8-9c8aa0382b6d

The open-access MAF lists 77 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 17, Frame Shift Del 9, In Frame Del 3, Nonsense Mutation 2, 3'UTR 2, Nonstop Mutation 2, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC5 | c.56G>C p.S19T | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV55587416; called by muse, varscan2
- ARMC1 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52533063, COSV52535120; called by muse, mutect2, varscan2
- ATR | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.933); catalogued as COSV63384124; called by muse, varscan2
- BAHD1 | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV69083659; called by muse, mutect2, varscan2
- C12orf29 | c.814T>A p.C272S | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58349017; called by muse, mutect2, varscan2
- CC2D1A | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV58781309; called by muse, mutect2, varscan2
- CHRNB1 | c.491A>T p.N164I | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53439032; called by muse, mutect2, varscan2
- COG8 | c.1328T>A p.L443Q | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54741758; called by muse, mutect2, varscan2
- COL12A1 | c.4060C>A p.H1354N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59390052; called by muse, mutect2, varscan2
- CP | c.1093A>C p.N365H | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.367); catalogued as COSV52829166; called by muse, mutect2
- CYP2A6 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV56533859; called by muse, mutect2, varscan2
- DDX41 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV57902138; called by muse, mutect2, varscan2
- DNAH1 | c.11110T>A p.S3704T | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70226707; called by muse, mutect2, varscan2
- EML5 | c.4241A>C p.N1414T (on ENST00000380664; = p.N1422T on NM_183387.3) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61342149; called by muse, mutect2, varscan2
- EPC1 | c.1507A>T p.T503S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV53923370; called by muse, mutect2, varscan2
- EPHA3 | c.2104A>C p.M702L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs766217704, COSV60695061; called by muse, mutect2, varscan2
- FREM2 | c.871G>C p.A291P | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs982499550, COSV54829535; called by muse, mutect2, varscan2
- GRAMD1A | c.938C>G p.P313R | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.901); catalogued as COSV58765888; called by muse, mutect2, varscan2
- GRID2 | c.2404C>T p.H802Y | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV56175708; called by muse, mutect2, varscan2
- IDH3B | c.1157A>T p.*386Lext*29 | Nonstop Mutation (SNP) | VAF 21/200 reads (11%) | catalogued as COSV61388937; called by muse, varscan2
- IDH3B | c.1156T>G p.*386Eext*29 | Nonstop Mutation (SNP) | VAF 20/200 reads (10%) | catalogued as COSV61388944; called by muse, varscan2
- IKZF2 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59576721; called by muse, mutect2, varscan2
- KRT84 | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57770695; called by muse, mutect2
- LRIG1 | c.1653G>C p.Q551H | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV56237107; called by muse, mutect2, varscan2
- MBL2 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64758025; called by muse, mutect2, varscan2
- MTF1 | c.1208C>A p.S403* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV65988405; called by muse, mutect2, varscan2
- MYO1G | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV51853234; called by muse, mutect2, varscan2
- OBSCN | c.5908G>C p.V1970L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV52743615; called by muse, mutect2, varscan2
- OCRL | c.155T>G p.V52G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV63980182; called by muse, mutect2, varscan2
- PANX1 | c.363C>G p.Y121* | Nonsense Mutation (SNP) | VAF 37/163 reads (23%) | catalogued as COSV57132726; called by muse, mutect2, varscan2
- PLEKHH1 | c.1687C>A p.R563S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV61280495; called by muse, mutect2, varscan2
- RNF213 | c.9493del p.L3165Sfs*70 | Frame Shift Del (DEL) | VAF 38/167 reads (23%) | catalogued as COSV60390446; called by mutect2, pindel, varscan2
- RPH3A | c.1879C>A p.H627N (on ENST00000389385 / NM_001143854.2; = p.H623N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV66990028; called by muse, mutect2, varscan2
- SCN8A | c.4541T>A p.I1514N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV61976829; called by muse, mutect2, varscan2
- SEC31A | c.2501A>C p.H834P (on ENST00000355196 / NM_001318120.1; = p.H795P on NM_016211.4) | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.125); catalogued as COSV52341648; called by muse, mutect2, varscan2
- SLC25A19 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as COSV57467035; called by muse, mutect2, varscan2
- SLC25A44 | c.20T>C p.I7T | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63961487; called by muse, mutect2, varscan2
- SLC35G6 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as COSV59489526, COSV59489553; called by muse, mutect2, varscan2
- SOGA1 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV52912166; called by muse, mutect2, varscan2
- TMC1 | c.453+2T>C p.X151_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as CS140342, COSV52768071; called by muse, mutect2, varscan2
- UBR1 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs1387789565, COSV51926439, COSV99316642; called by muse, mutect2, varscan2
- UTP6 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV55571628; called by muse, mutect2, varscan2
- ZEB2 | c.1364G>A p.S455N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57951852, COSV57955830; called by muse, mutect2, varscan2
- ZNF154 | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV70744755; called by muse, mutect2, varscan2
- ZNF469 | c.3599C>T p.P1200L (on ENST00000437464; = p.P1228L on NM_001367624.2) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV71258266; called by muse, mutect2, varscan2
- ANKS4B | c.122del p.Y41Sfs*8 | Frame Shift Del (DEL) | VAF 39/138 reads (28%) | called by mutect2, pindel, varscan2
- CLTC | c.3764_3765del p.E1255Gfs*27 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | called by pindel, varscan2
- LRRC42 | c.198_205del p.K66Nfs*2 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | called by mutect2, pindel, varscan2
- MSH6 | c.763dup p.E255Gfs*3 | Frame Shift Ins (INS) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- OR6K6 | c.266del p.F89Sfs*25 (on ENST00000368144; = p.F65Sfs*25 on NM_001005184.1) | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel, varscan2
- PKDCC | c.1025_1033del p.N342_Y344del | In Frame Del (DEL) | VAF 21/184 reads (11%) | called by mutect2, pindel
- POLG | c.975del p.T326Qfs*39 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- PPP1R15B | c.1451_1453del p.V484del | In Frame Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- RAB15 | c.205_210del p.R69_Y70del | In Frame Del (DEL) | VAF 16/121 reads (13%) | called by mutect2, pindel, varscan2
- RNASEH2C | c.194del p.G65Afs*19 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- SLC24A5 | c.1016del p.F339Sfs*20 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | called by mutect2, pindel
- STAG2 | c.1290del p.E430Dfs*18 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, varscan2
- CCDC86 | c.30G>T p.R10= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs760505982, COSV57124522; called by muse, mutect2, varscan2
- FOXO4 | c.96C>T p.T32= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV58574753; called by muse, mutect2, varscan2
- HMCN1 | c.7092T>A p.V2364= | Silent (SNP) | VAF 39/238 reads (16%) | catalogued as COSV54879377; called by muse, mutect2, varscan2
- IDH3B | c.1158G>A p.*386= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as COSV61388932; called by muse, varscan2
- LPCAT3 | c.96G>A p.A32= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV54644851; called by muse, mutect2, varscan2
- MMS22L | c.2310T>A p.I770= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV51516936; called by muse, mutect2, varscan2
- MTOR | c.3636C>T p.L1212= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV63868644; called by muse, mutect2, varscan2
- NELFB | c.993G>A p.L331= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58023787; called by muse, mutect2, varscan2
- REC114 | c.126G>T p.L42= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV58521355; called by muse, mutect2
- RIMS3 | c.156G>A p.K52= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV65503932; called by muse, mutect2, varscan2
- SERINC1 | c.250T>C p.L84= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV60101497; called by muse, mutect2, varscan2
- SLC52A1 | c.381C>A p.T127= | Silent (SNP) | VAF 38/142 reads (27%) | called by mutect2, varscan2
- SP4 | c.552T>C p.T184= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV56020930; called by muse, mutect2, varscan2
- USH2A | c.14769C>A p.I4923= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as COSV56331325, COSV56372861; called by muse, mutect2, varscan2
- WDR20 | c.1830T>A p.T610= (on ENST00000424963 / NM_001330228.2; = p.T579= on NM_181291.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/210 reads (18%) | catalogued as COSV51963370; called by muse, mutect2, varscan2
- ZCCHC10 | c.184A>C p.R62= (on ENST00000509437 / NM_001300818.3; = p.R40= on NM_017665.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV60772416; called by muse, mutect2, varscan2
- ZNF235 | c.744A>G p.V248= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV52155201; called by muse, mutect2, varscan2
- CLDN9 | c.*459C>A | 3'UTR (SNP) | VAF 30/105 reads (29%) | catalogued as COSV100172070; called by muse, mutect2, varscan2
- CSMD2 | c.6862+712G>C | Intron (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- MED1 | c.*2207C>T | 3'UTR (SNP) | VAF 27/77 reads (35%) | catalogued as COSV99233801; called by muse, mutect2, varscan2
